Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4872, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4872-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT RADICAL NEPHRECTOMY AND EN BLOCK LYMPH NODES:

RENAL CELL CARCINOMA, CONVENTIONAL (90% CLEAR CELLS, 10% EOSINOPHILIC CELLS), FUHRMAN'S NUCLEAR GRADE 4. (SEE COMMENT)

TUMOR MEASURES 4.5 CM IN MAXIMUM DIMENSION.

NO EXTENSION INTO THE PERINEPHRIC ADIPOSE TISSUE. (SEE COMMENT)

Vascular and ureteral margins free of tumor.

One lymph node with lipid granulomas, no tumor present (0/1).

COMMENT

The tumor measures 4.0 x 3.0 x 3.0 cm and contains areas with marked anaplasia; however, these areas are not diagnostic of sarcomatoid dedifferentiation.

The tumor focally bulges into the renal sinus adipose tissue without infiltrative borders.

GROSS DESCRIPTION

(A) RIGHT RADICAL NEPHRECTOMY AND EN BLOCK LYMPH NODES - A radical nephrectomy specimen including the kidney (12.0 x 5.0 x 5.0 cm) with attached Gerota's fascia (18.0 x 11.0 x 7.0 cm overall). No adrenal gland is identified.

Located in the middle portion of the kidney is well-circumscribed brown-yellow tumor with focal hemorrhage (4.5 x 3.0 x 3.0 cm). No necrosis is identified. The tumor is confined to the kidney and approaches the renal capsule but the renal capsule still intact. No invasion of the renal sinus or renal vein is identified. The Gerota's fascia is free of tumor.

One unremarkable lymph node is identified (2.0 x 1.5 x 1.0 cm).

SECTION CODE: C1, vascular and ureteral resection margin; A2-A10, tumor with adjacent kidney and renal capsule; A11, A12, tumor with renal sinus; A13-A15, one lymph node; A16, Gerota's fascia, en face. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123

[REDACTED]

Source: NCI Genomic Data Commons file 533493ab-3f72-4e82-af5b-902f5d10389b (TCGA-CJ-4872.49FDE6D7-CF1F-40CE-BF4A-2FA567EE253A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).